Somatic mutation profile of tumor specimen fe4b3b1c-9f7f-4109-8a76-ca1d6f (aliquot fe4b3b1c-9f7f-4109-8a76-ca1d6f_D6_1) from CPTAC case 11CO060, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen fe4b3b1c-9f7f-4109-8a76-ca1d6f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b63a39a-4725-4fc4-9eb8-efa90980cd17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 04373565-6aca-4d46-a6f3-abb811 (Blood Derived Normal), aliquot 04373565-6aca-4d46-a6f3-abb811_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4910c3b-ee67-4220-95e9-1a98229e2227

The open-access MAF lists 130 somatic variants for this specimen: 92 protein-altering or splice-affecting, 26 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 26, Nonsense Mutation 10, Intron 4, RNA 4, 5'UTR 3, Frame Shift Del 3, Splice Region 1, 3'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 122/253 reads (48%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 193/291 reads (66%) | hotspot (GDC flag); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs757974181; called by muse, mutect2, varscan2
- ASPHD1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs185373918; called by muse, mutect2, varscan2
- BCOR | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 200/735 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs960778355, COSV60699113; called by muse, mutect2, varscan2
- BRF2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs138178332; called by muse, mutect2, varscan2
- CABP2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 152/340 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53709520; called by muse, mutect2, varscan2
- CACNA1B | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199937787; called by muse, mutect2, varscan2
- CC2D1B | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV52561834; called by muse, mutect2, varscan2
- CSMD3 | c.6427C>G p.L2143V (on ENST00000297405 / NM_001363185.1; = p.L2039V on NM_052900.3) | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); catalogued as COSV99827672; called by muse, mutect2, varscan2
- CTSE | c.1141C>T p.R381* (on ENST00000360218; = p.R376* on NM_001910.4) | Nonsense Mutation (SNP) | VAF 32/563 reads (6%) | catalogued as rs572870573; called by muse, mutect2
- CYP2A13 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752624803; called by muse, varscan2
- DCLK1 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99712930; called by muse, mutect2, varscan2
- DMD | c.4604C>T p.T1535M | Missense Mutation (SNP) | VAF 120/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1431604157, COSV100822817, COSV63771742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.4325T>C p.V1442A (on ENST00000409039; = p.V1381A on NM_207437.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1273523262; called by muse, mutect2, varscan2
- DSPP | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 76/305 reads (25%) | catalogued as COSV56809682; called by muse, mutect2, varscan2
- ECD | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs149473721; called by mutect2, varscan2
- EPHA7 | c.1877A>G p.K626R | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); catalogued as COSV65184279; called by muse, mutect2, varscan2
- GJA5 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 213/722 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs782392307, COSV54784982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRB10 | c.1369G>A p.E457K (on ENST00000398812; = p.E411K on NM_001001549.3) | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60010450; called by muse, mutect2, varscan2
- ITGA1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 115/194 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs150093672, COSV50890398; called by muse, mutect2, varscan2
- KCNA4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs768852661, COSV60251924, COSV60255631; called by muse, mutect2, varscan2
- KDM1B | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV99924703; called by muse, mutect2, varscan2
- KIF26A | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99043655; called by muse, mutect2, varscan2
- KLRK1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs774615042, COSV53698235; called by muse, mutect2, varscan2
- MICAL1 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 289/473 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs1344640261; called by mutect2, varscan2
- MMP19 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs779486182, COSV59453183; called by muse, mutect2, varscan2
- NAT14 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as rs781493413, COSV52697879, COSV52700525; called by muse, mutect2, varscan2
- NEK5 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV62882137; called by muse, mutect2
- NKAPL | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 147/195 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs570929796, COSV100642464; called by muse, mutect2, varscan2
- NUP153 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as rs543593216, COSV50451937; called by muse, mutect2, varscan2
- NUPR2 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1322278788; called by muse, mutect2, varscan2
- OR11H12 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs775822725; called by muse, mutect2, varscan2
- OR2T8 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs145320774; called by muse, mutect2, varscan2
- PECR | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as rs771102215; called by muse, mutect2, varscan2
- PER3 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs551012021; called by muse, mutect2, varscan2
- PLA2G6 | c.2075C>A p.S692Y | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59269193; called by muse, mutect2
- POLI | c.1298T>G p.V433G | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54190954; called by muse, mutect2, varscan2
- PPIAL4G | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV70087597; called by mutect2, varscan2
- PTCHD1 | c.1937G>T p.R646I | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65062719; called by muse, mutect2, varscan2
- RIMS2 | c.2950G>T p.D984Y (on ENST00000666250 / NM_001348490.2; = p.D792Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51689157; called by muse, mutect2, varscan2
- RPUSD3 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 85/196 reads (43%) | catalogued as rs771967952; called by muse, mutect2, varscan2
- SGO2 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773911976, COSV63415656; called by mutect2, varscan2
- SLX4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410797507, COSV53561106; called by muse, mutect2, varscan2
- SVIL | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs143918159; called by muse, mutect2
- SYT3 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs766336772, COSV58895965; called by muse, mutect2, varscan2
- THSD7A | c.3422T>C p.V1141A | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1414457881; called by muse, mutect2, varscan2
- TNRC6B | c.4501A>G p.T1501A (on ENST00000454349 / NM_001162501.2; = p.T1391A on NM_015088.3) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100110196; called by muse, mutect2, varscan2
- UBAP1L | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1195023884; called by mutect2, varscan2
- ZKSCAN7 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as rs368452398; called by muse, mutect2
- A2M | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAD1 | c.1322C>A p.S441* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- ADCY2 | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- ADGRE3 | c.1812+1G>A p.X604_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- ANO7 | c.2546T>G p.I849S (on ENST00000274979; = p.I795S on NM_001370694.2) | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2
- ATRNL1 | c.4007C>A p.P1336H | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD3 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- CADPS | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC125 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- CES5A | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP94 | c.386A>T p.E129V (on ENST00000320267 / NM_001352064.2; = p.E135V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CREB5 | c.659G>C p.C220S (on ENST00000357727 / NM_182898.4; = p.C213S on NM_004904.3) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DDX47 | c.483A>T p.K161N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLG2 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM189A1 | c.1528C>A p.H510N | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- FMR1 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GALNTL6 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK2 | c.1555A>G p.I519V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HERC2 | c.11513G>A p.G3838D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFFO2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- KIF1B | c.2563A>G p.M855V (on ENST00000377086 / NM_001365952.1; = p.M809V on NM_015074.3) | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- LMOD2 | c.1146A>T p.R382S | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- LPP | c.298A>T p.K100* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- MMGT1 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NPHP3 | c.1350+7A>G | Splice Region (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- NXNL2 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.071); called by muse, varscan2
- OGDH | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR4M1 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR52E2 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 144/344 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.740A>G p.E247G (on ENST00000259318 / NM_001136562.3; = p.E478G on NM_007203.5) | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- PARP9 | c.1858T>C p.W620R | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEAK1 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RAB2A | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD51AP2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SLC29A2 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 197/652 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); called by mutect2, varscan2
- SLC9C2 | c.2942G>C p.G981A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SPPL2C | c.1808del p.G603Afs*23 | Frame Shift Del (DEL) | VAF 168/311 reads (54%) | called by mutect2, varscan2
- TMEM102 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 94/147 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TMEM260 | c.1310T>C p.L437S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TMPRSS9 | c.2919_2924del p.A974_P975del (on ENST00000648592; = p.A940_P941del on NM_182973.2) | In Frame Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- TTLL2 | c.1352_1355del p.D451Vfs*25 | Frame Shift Del (DEL) | VAF 24/141 reads (17%) | called by mutect2, pindel, varscan2
- WNK3 | c.128del p.N43Tfs*11 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- ABCC9 | c.48C>T p.N16= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs199631710, COSV53973477, COSV99686899; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMKK2 | c.285C>T p.S95= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as rs143144419; called by muse, mutect2, varscan2
- CCDC85A | c.888G>A p.P296= | Silent (SNP) | VAF 86/393 reads (22%) | catalogued as rs556270823; called by muse, mutect2, varscan2
- CDCA5 | c.598C>A p.R200= | Silent (SNP) | VAF 47/175 reads (27%) | called by muse, mutect2, varscan2
- CPT1C | c.1842G>A p.R614= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- CREBBP | c.5373G>A p.S1791= | Silent (SNP) | VAF 68/301 reads (23%) | catalogued as rs749762107, COSV52137631; called by muse, mutect2, varscan2
- CSMD2 | c.4698C>T p.N1566= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as rs377415018; called by muse, mutect2, varscan2
- DNAJC14 | c.57T>A p.G19= | Silent (SNP) | VAF 64/184 reads (35%) | called by muse, varscan2
- FCER2 | c.612G>A p.P204= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as rs375077946, COSV100689683; called by muse, mutect2, varscan2
- GABRB3 | c.1266G>A p.P422= | Silent (SNP) | VAF 65/335 reads (19%) | catalogued as rs377621777; called by muse, mutect2, varscan2
- GABRG2 | c.1230T>C p.D410= (on ENST00000361925 / NM_001375343.1; = p.D370= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs201824364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSX2 | c.345C>T p.D115= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- HSPA12A | c.1362G>A p.P454= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as rs782557265, COSV65022960; called by muse, mutect2, varscan2
- MELTF | c.633C>T p.S211= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs995978520; called by muse, mutect2, varscan2
- MYO10 | c.2487G>A p.K829= | Silent (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- NAALADL1 | c.1533C>T p.S511= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- PRSS56 | c.786C>A p.P262= | Silent (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- PTPN13 | c.2823G>A p.S941= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as rs748274481; called by muse, varscan2
- RAPGEF5 | c.813C>T p.V271= (on ENST00000401957 / NM_001367602.2; = p.V574= on NM_012294.5) | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs751759222, COSV59792304; called by muse, mutect2, varscan2
- SCX | c.441C>T p.P147= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- SHH | c.834C>T p.N278= | Silent (SNP) | VAF 56/161 reads (35%) | called by muse, mutect2, varscan2
- SRCIN1 | c.1482G>A p.P494= (on ENST00000621492; = p.P460= on NM_025248.3) | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs909300368; called by muse, mutect2, varscan2
- ST6GAL2 | c.819G>A p.A273= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs1437979462, COSV64527305; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.660C>T p.L220= | Silent (SNP) | VAF 91/247 reads (37%) | catalogued as rs147120861; called by muse, mutect2, varscan2
- TBKBP1 | c.1656C>T p.P552= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as rs747777676; called by muse, mutect2, varscan2
- TIMELESS | c.2472C>T p.P824= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as rs756306792, COSV99973845; called by muse, mutect2, varscan2
- AC021218.1 | n.739C>G | RNA (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- B2M | c.-25T>G | 5'UTR (SNP) | VAF 56/345 reads (16%) | called by muse, mutect2, varscan2
- BABAM2 | c.-11G>A | 5'UTR (SNP) | VAF 17/76 reads (22%) | catalogued as rs1289553037; called by muse, mutect2, varscan2
- CDH2 | c.173-22643T>C | Intron (SNP) | VAF 7/54 reads (13%) | catalogued as rs764388637; called by mutect2, varscan2
- DEF8 | c.1186-35C>T | Intron (SNP) | VAF 66/323 reads (20%) | catalogued as rs191061981; called by muse, mutect2, varscan2
- FAM90A27P | n.847A>T | RNA (SNP) | VAF 40/175 reads (23%) | called by muse, mutect2, varscan2
- HOXA10 | c.*146C>T | 3'UTR (SNP) | VAF 176/448 reads (39%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110237C>T | Intron (SNP) | VAF 53/129 reads (41%) | catalogued as rs1261704733; called by muse, mutect2, varscan2
- NUTM2D | c.-56C>T | 5'UTR (SNP) | VAF 14/391 reads (4%) | catalogued as rs1270345241; called by muse, mutect2
- SSPOP | n.6390G>A | RNA (SNP) | VAF 91/235 reads (39%) | catalogued as rs754181529; called by muse, mutect2, varscan2
- TPRXL | n.724C>T | RNA (SNP) | VAF 56/291 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.34265-5041A>T | Intron (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
